FM case AD8593 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/f3b20dd4-640f-4b5d-92dd-83f912e93fa1

Female, 63.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the breast; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
